Somatic mutation profile of tumor specimen TCGA-B6-A0IC-01A (aliquot TCGA-B6-A0IC-01A-11W-A050-09) from TCGA case TCGA-B6-A0IC, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Intraductal papillary adenocarcinoma with invasion; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage X; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-B6-A0IC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a981940-80b7-4c90-9d18-9823160e129a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0IC-10A (Blood Derived Normal), aliquot TCGA-B6-A0IC-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe70ec36-c7f2-4937-85ca-15813f0badfe

The open-access MAF lists 39 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 8, Frame Shift Del 3, Frame Shift Ins 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 65/155 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARHGAP35 | c.4001C>T p.P1334L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1278020073, COSV68331616, COSV68331861; called by muse, mutect2, varscan2
- BDP1 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV62431626; called by muse, mutect2, varscan2
- CEP350 | c.5901del p.S1968Vfs*11 | Frame Shift Del (DEL) | VAF 95/252 reads (38%) | catalogued as COSV100854594; called by mutect2, pindel, varscan2
- CROT | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 84/147 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58974550; called by muse, mutect2, varscan2
- DSCAM | c.5032A>G p.I1678V | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV68027253; called by muse, mutect2, varscan2
- FRMPD4 | c.1755C>A p.S585R | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV66215339; called by muse, mutect2, varscan2
- KRT1 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1184058811, COSV52866046; called by muse, mutect2, varscan2
- MAP3K4 | c.1340C>T p.T447I | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.189); catalogued as COSV62334025; called by muse, mutect2, varscan2
- MFN2 | c.1055C>A p.S352Y | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52422614; called by muse, mutect2, varscan2
- NAA10 | c.281C>A p.A94D | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV64169864; called by muse, mutect2, varscan2
- NLGN3 | c.2341dup p.H781Pfs*2 (on ENST00000358741 / NM_181303.2; = p.H761Pfs*2 on NM_018977.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 11/71 reads (15%) | catalogued as rs760052938; called by mutect2, varscan2
- OLFM4 | c.1005C>A p.N335K | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.92); PolyPhen benign (0.029); catalogued as COSV54577604; called by muse, mutect2, varscan2
- PCDH15 | c.1759G>T p.D587Y | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57317149; called by muse, mutect2, varscan2
- PRPF3 | c.770T>C p.I257T | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV61394895; called by muse, mutect2, varscan2
- PTPN5 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs202181774; called by muse, mutect2, varscan2
- SATB2 | c.1882A>T p.I628F | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53484340; called by muse, mutect2, varscan2
- SDK1 | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs555051428, COSV67369883; called by muse, mutect2, varscan2
- SLC10A6 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV56721756; called by muse, mutect2, varscan2
- SMCR8 | c.1476C>A p.S492R | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV58177692; called by mutect2, varscan2
- STARD8 | c.333G>T p.Q111H | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52926923, COSV52931216; called by muse, mutect2, varscan2
- TEX15 | c.3986G>A p.S1329N (on ENST00000256246; = p.S1712N on NM_001350162.2) | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as COSV99822202; called by muse, mutect2
- TIMMDC1 | c.638C>G p.S213C | Missense Mutation (SNP) | VAF 111/227 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51786748; called by muse, mutect2, varscan2
- TTL | c.971A>G p.E324G | Missense Mutation (SNP) | VAF 84/164 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV51974773; called by muse, mutect2, varscan2
- WSCD2 | c.1606C>A p.Q536K | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV54583444; called by muse, mutect2, varscan2
- DUSP16 | c.905dup p.G303Wfs*19 | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.689T>A p.M230K | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TUT7 | c.674_679delinsC p.K225Tfs*4 | Frame Shift Del (DEL) | VAF 122/390 reads (31%) | called by pindel, varscan2*
- ZFYVE9 | c.1423_1426del p.S475Mfs*27 | Frame Shift Del (DEL) | VAF 46/111 reads (41%) | called by pindel, varscan2
- ALDH1A1 | c.537G>A p.K179= | Silent (SNP) | VAF 53/125 reads (42%) | catalogued as COSV52791615; called by muse, mutect2, varscan2
- COL6A6 | c.2577G>A p.V859= | Silent (SNP) | VAF 7/181 reads (4%) | catalogued as COSV100650990; called by muse, mutect2
- DNAH3 | c.2346A>G p.A782= | Silent (SNP) | VAF 125/377 reads (33%) | catalogued as COSV54524300; called by muse, mutect2, varscan2
- LMOD1 | c.390A>G p.L130= | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as COSV66172786; called by muse, mutect2, varscan2
- RNF123 | c.2610C>A p.A870= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV57538711; called by muse, mutect2, varscan2
- SLC13A2 | c.501C>T p.N167= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs192486018, COSV58995207; called by muse, mutect2, varscan2
- SLC5A12 | c.573C>T p.V191= | Silent (SNP) | VAF 43/151 reads (28%) | catalogued as COSV54821751; called by muse, mutect2, varscan2
- ZNF354C | c.72C>T p.D24= | Silent (SNP) | VAF 76/325 reads (23%) | catalogued as rs751805522, COSV59607055; called by muse, mutect2, varscan2
- GPRC5A | c.*3378G>A | 3'UTR (SNP) | VAF 80/152 reads (53%) | catalogued as rs746213363, COSV50007766; called by muse, mutect2, varscan2
- GPRC5A | c.*3379C>A | 3'UTR (SNP) | VAF 81/154 reads (53%) | catalogued as COSV50007771; called by muse, mutect2, varscan2
